Somatic mutation profile of tumor specimen TCGA-VQ-A91K-01A (aliquot TCGA-VQ-A91K-01A-11D-A410-08) from TCGA case TCGA-VQ-A91K, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 69.6 years (25,424 days).
Specimen TCGA-VQ-A91K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 873c1e59-6d10-4c82-b8ea-0b3113a8cd9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91K-10A (Blood Derived Normal), aliquot TCGA-VQ-A91K-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3606a6a5-376a-4c0d-a56a-3af5fe52a5ed

The open-access MAF lists 1,562 somatic variants for this specimen: 1,163 protein-altering or splice-affecting, 359 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 779, Silent 359, Frame Shift Del 256, Frame Shift Ins 48, Nonsense Mutation 45, Intron 15, In Frame Del 13, RNA 12, Splice Site 11, Splice Region 10, 3'UTR 4, 3'Flank 4.

Variants (750 of 1,562; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD11 | c.3309del p.D1104Mfs*214 | Frame Shift Del (DEL) | VAF 57/147 reads (39%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- BIVM-ERCC5 | c.4113del p.K1371Nfs*65 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs752661599, COSV100863757; ClinVar: pathogenic; called by mutect2, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CHD2 | c.3734del p.K1245Nfs*4 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as rs752940775; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352del p.R785Efs*32 (on ENST00000651564; = p.R738Efs*32 on NM_015692.5) | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CRYBB2 | c.583T>G p.W195G | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs147344332, CM162361, COSV101236780; ClinVar: likely pathogenic; called by muse, varscan2
- DMD | c.5697del p.K1899Nfs*2 | Frame Shift Del (DEL) | VAF 15/31 reads (48%) | catalogued as rs794727661, CD050845, CD093452; ClinVar: pathogenic; called by mutect2, varscan2
- GAA | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs141533320, CM060280; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GPR179 | c.278del p.P93Qfs*57 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs794726685, CD121153; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 12/83 reads (14%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PAX2 | c.76dup p.V26Gfs*28 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs75462234; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 29/79 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RPGR | c.2520+1412dup | Intron (INS) | VAF 47/83 reads (57%) | catalogued as rs886041376; ClinVar: pathogenic; called by mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs397515538; ClinVar: pathogenic; called by mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TTN | c.101706del p.A33903Pfs*2 (on ENST00000591111; = p.A26479Pfs*2 on NM_003319.4) | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs869312069, CD1514610; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ABCA2 | c.6217C>T p.R2073W (on ENST00000614293; = p.R2043W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754774965, COSV99687864; called by muse, mutect2, varscan2
- ABCA8 | c.4339C>T p.R1447* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as rs200550454, COSV99287141; called by muse, mutect2, varscan2
- ABCA8 | c.2860C>A p.L954I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99287143; called by muse, mutect2, varscan2
- ABCA9 | c.3505A>G p.M1169V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100383607; called by muse, mutect2, varscan2
- ABCB5 | c.3056A>C p.E1019A (on ENST00000404938 / NM_001163941.2; = p.E574A on NM_178559.6) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV99330051; called by muse, varscan2
- ABCC10 | c.392G>A p.R131Q (on ENST00000372530 / NM_001198934.2; = p.R88Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1327817713, COSV99766828, COSV99768148; called by muse, mutect2, varscan2
- ABCC4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs142182014; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCC6 | c.4394A>T p.D1465V | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99229840; called by muse, mutect2
- AC004832.3 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99840994; called by muse, mutect2, varscan2
- ACAN | c.7318C>T p.R2440C (on ENST00000560601 / NM_001369268.1; = p.R2364C on NM_001135.3) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751606366, COSV100613894; called by muse, mutect2, varscan2
- ACAT2 | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100887205; called by muse, mutect2, varscan2
- ACBD3 | c.568del p.R190Gfs*43 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs757016425; called by mutect2, varscan2
- ACKR4 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422335919, COSV99392792; called by muse, mutect2, varscan2
- ACTR6 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1168957423, COSV99498824; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs553414033, COSV57430841; called by muse, mutect2
- ADAM19 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs141344301; called by muse, mutect2, varscan2
- ADAMTS16 | c.2494G>T p.G832* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV57007658, COSV99943421; called by muse, mutect2
- ADAMTS3 | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs374131974; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3705G>T p.Q1235H | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.832); catalogued as COSV99718241, COSV99721668; called by muse, mutect2, varscan2
- ADAR | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.255); catalogued as COSV99426884; called by muse, mutect2, varscan2
- ADCY10 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs779053477, COSV63240979; called by muse, mutect2, varscan2
- ADCY5 | c.2482G>A p.V828M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs116775208; called by muse, mutect2, varscan2
- ADCY5 | c.2002G>A p.G668R | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.227); catalogued as rs1289190687, COSV59197933; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776693044, COSV66924677; called by muse, mutect2, varscan2
- ADGRB1 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100030552; called by muse, mutect2
- ADGRB2 | c.697T>G p.S233A | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV99927108; called by muse, mutect2, varscan2
- ADGRF1 | c.96del p.E33Nfs*4 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | catalogued as rs771491120; called by mutect2, pindel, varscan2
- ADGRG1 | c.843del p.S281Rfs*42 | Frame Shift Del (DEL) | VAF 23/55 reads (42%) | catalogued as COSV65636865; called by mutect2, pindel, varscan2
- ADGRL2 | c.3403C>T p.R1135C (on ENST00000370717 / NM_001366005.1; = p.R1122C on NM_012302.4) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014195159, COSV54655645; called by muse, mutect2
- AGBL1 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759191613, COSV66848829; called by mutect2, varscan2
- AGBL1 | c.2598G>C p.W866C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101224384; called by muse, mutect2
- AGO3 | c.807A>C p.E269D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); catalogued as COSV99869558; called by muse, mutect2, varscan2
- AGTPBP1 | c.1240C>T p.R414* (on ENST00000357081 / NM_001330701.2; = p.R374* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as rs1183456608, COSV100430404; called by muse, mutect2, varscan2
- AHCTF1 | c.6343C>T p.Q2115* (on ENST00000366508; = p.Q2089* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100404568; called by muse, mutect2, varscan2
- AHNAK2 | c.9686T>C p.L3229S | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV100319216; called by muse, mutect2
- AHNAK2 | c.9191T>C p.L3064S | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100319217; called by muse, mutect2
- AHNAK2 | c.5375A>T p.D1792V | Missense Mutation (SNP) | VAF 122/330 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100319218; called by muse, varscan2
- AKAP9 | c.1287G>C p.K429N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100663310; called by muse, mutect2, varscan2
- AKAP9 | c.6656G>A p.R2219Q (on ENST00000359028; = p.R2195Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.77); catalogued as rs551807012, COSV100663311; called by muse, mutect2, varscan2
- AKT1S1 | c.495del p.T166Pfs*87 (on ENST00000344175 / NM_001098633.4; = p.T186Pfs*87 on NM_032375.5) | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as rs748776119, COSV59276444; called by mutect2, pindel, varscan2
- ALG1L | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs368430945; called by muse, mutect2, varscan2
- ALOX12B | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100047855; called by muse, mutect2, varscan2
- ALOXE3 | c.913G>C p.A305P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV100560055; called by muse, mutect2, varscan2
- ALX3 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63928754; called by muse, mutect2
- AMOTL1 | c.883T>C p.S295P | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as rs1565357377, COSV100133972; called by muse, mutect2, varscan2
- AMOTL2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99850750; called by muse, mutect2, varscan2
- ANAPC2 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.097); catalogued as rs781263969, COSV100119262; called by muse, mutect2, varscan2
- ANK3 | c.12420del p.K4140Nfs*15 (on ENST00000280772 / NM_001320874.2; = p.K661Nfs*15 on NM_001149.3) | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs1466658148; called by mutect2, pindel, varscan2
- ANKRD13A | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55675585; called by muse, mutect2, varscan2
- ANKRD13B | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1249129559, COSV100801475; called by muse, mutect2, varscan2
- ANO3 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1352571478, COSV99879605; called by muse, mutect2, varscan2
- ANO7 | c.1486C>T p.R496C (on ENST00000274979; = p.R442C on NM_001370694.2) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs757887974, COSV51470633; called by muse, mutect2, varscan2
- ANPEP | c.2507_2508del p.K836Rfs*53 | Frame Shift Del (DEL) | VAF 19/63 reads (30%) | catalogued as rs1567154961; called by mutect2, pindel, varscan2
- ANXA13 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV99147259; called by muse, mutect2, varscan2
- AOX1 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV65982819; called by muse, mutect2, varscan2
- AP3B2 | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1234049432, COSV99917108; called by muse, mutect2, varscan2
- APBA1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs750949378, COSV99596878, COSV99597344; called by muse, mutect2
- APLP2 | c.1387A>G p.M463V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs777855761, COSV99600158; called by muse, mutect2, varscan2
- APOA5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs781109287, COSV99911196, COSV99911379; called by muse, mutect2, varscan2
- AR | c.2333A>C p.K778T | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.977); catalogued as COSV65957933, COSV65958597; called by muse, mutect2, varscan2
- ARHGAP33 | c.2996G>A p.R999Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs200766421; called by muse, mutect2, varscan2
- ARHGAP44 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99311682; called by muse, mutect2, varscan2
- ARHGEF28 | c.2144T>G p.I715S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.189); catalogued as COSV99710371; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | catalogued as COSV61389445; called by mutect2, varscan2
- ARRDC4 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs778751326, COSV99164561; called by muse, mutect2, varscan2
- ART1 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51705885; called by muse, mutect2, varscan2
- ASCC2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143452344, COSV100316549; called by muse, mutect2, varscan2
- ASIC1 | c.529del p.E177Rfs*31 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV57319909; called by mutect2, pindel, varscan2
- ASIC3 | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as rs747352796, COSV99877507; called by muse, mutect2, varscan2
- ASPM | c.5199C>G p.I1733M | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54137168; called by muse, mutect2, varscan2
- ASTL | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs754272008, COSV100668228, COSV60904803; called by muse, mutect2, varscan2
- ASTN1 | c.2435G>A p.R812Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs757289219, COSV99923390; called by muse, mutect2, varscan2
- ATG16L1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100731277, COSV100731443; called by muse, mutect2, varscan2
- ATN1 | c.3461C>T p.A1154V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1565570230, COSV99980857; called by muse, mutect2, varscan2
- ATP10A | c.4276del p.L1426Cfs*66 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | catalogued as rs768534594; called by mutect2, pindel, varscan2
- ATP10A | c.2237G>A p.R746H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791626, COSV63516234; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1A4 | c.2527A>G p.R843G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV100927660; called by muse, mutect2, varscan2
- ATP2B2 | c.1309G>A p.V437M (on ENST00000352432; = p.V403M on NM_001683.5) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1276448598, COSV59493220; called by muse, mutect2, varscan2
- ATP6V0D1 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1365735194, COSV99341398; called by muse, mutect2, varscan2
- ATP6V1D | c.153A>G p.I51M | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV99371005; called by muse, mutect2, varscan2
- ATP7B | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374592960; called by muse, mutect2, varscan2
- ATP8B1 | c.2373del p.P792Hfs*8 | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | catalogued as rs1568184131, COSV99377078; called by mutect2, pindel, varscan2
- ATP8B2 | c.1343G>T p.G448V (on ENST00000672630; = p.G415V on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100528308; called by muse, mutect2, varscan2
- ATP8B4 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as COSV99467977; called by muse, mutect2, varscan2
- ATXN1 | c.1486A>T p.S496C | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99788171; called by muse, mutect2, varscan2
- AUTS2 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV61419084; called by muse, mutect2, varscan2
- BBOF1 | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1246270199, COSV67454510; called by muse, mutect2, varscan2
- BBX | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100362368, COSV57892870; called by muse, mutect2, varscan2
- BCAM | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99539053; called by muse, mutect2, varscan2
- BCAS3 | c.2386C>T p.R796C (on ENST00000390652 / NM_001353144.2; = p.R781C on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs773996890, COSV66771266; called by muse, mutect2, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs754310793, COSV52681762; called by mutect2, pindel, varscan2
- BCLAF1 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs768982507, COSV62141484; called by muse, mutect2, varscan2
- BHLHE23 | c.527C>T p.A176V (on ENST00000370346; = p.A192V on NM_080606.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100947633; called by muse, mutect2
- BHLHE23 | c.356C>T p.A119V (on ENST00000370346; = p.A135V on NM_080606.4) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64846439; called by muse, mutect2
- BLM | c.3939G>T p.E1313D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100757360; called by muse, mutect2
- BLNK | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99814296; called by muse, mutect2, varscan2
- BMP4 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs748940819, COSV55415276; called by muse, mutect2, varscan2
- BRD7 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101165082; called by muse, mutect2
- BRF1 | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV100527886; called by muse, mutect2, varscan2
- BTBD11 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99777168; called by muse, mutect2, varscan2
- BTBD11 | c.1490G>T p.R497M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV55015804, COSV99775697; called by muse, mutect2, varscan2
- BUD13 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99496820; called by muse, mutect2, varscan2
- C12orf42 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs369075296, COSV59379261; called by muse, mutect2, varscan2
- C16orf89 | c.955+1G>C p.X319_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100281010; called by muse, varscan2
- C17orf64 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs759533511, COSV99293683; called by muse, varscan2
- C4BPB | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1400432189, COSV99700201; called by muse, mutect2, varscan2
- C5orf22 | c.772del p.S258Qfs*31 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as rs751259551; called by mutect2, varscan2
- C8orf33 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV100510455, COSV100510634; called by muse, mutect2, varscan2
- CA4 | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV56280835; called by muse, mutect2, varscan2
- CAAP1 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV61700397; called by muse, mutect2, varscan2
- CACNA1E | c.3381G>A p.M1127I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100705745; called by muse, mutect2, varscan2
- CACNA1S | c.2965G>A p.E989K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs922494615, COSV62943102; called by muse, mutect2, varscan2
- CACNA2D2 | c.2890G>A p.V964I (on ENST00000479441 / NM_001174051.3; = p.V957I on NM_006030.4) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99818494; called by muse, mutect2, varscan2
- CACNG7 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99712369; called by muse, mutect2, varscan2
- CADPS | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV99341448; called by muse, mutect2, varscan2
- CAND2 | c.2863del p.V955Wfs*12 (on ENST00000456430 / NM_001162499.2; = p.V862Wfs*12 on NM_012298.3) | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs780431641; called by mutect2, pindel, varscan2
- CASKIN1 | c.3533G>A p.R1178H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV58218847; called by muse, mutect2
- CATSPERG | c.2342C>T p.T781M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99287023; called by muse, mutect2
- CCDC107 | c.701_702del p.T234Rfs*40 | Frame Shift Del (DEL) | VAF 26/76 reads (34%) | catalogued as rs1473256144; called by pindel, varscan2
- CCDC146 | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV99593253; called by muse, mutect2, varscan2
- CCDC180 | c.500dup p.L167Ffs*6 | Frame Shift Ins (INS) | VAF 11/40 reads (28%) | catalogued as rs577900246; called by mutect2, varscan2
- CCDC27 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs560903163, COSV53899839; called by muse, mutect2, varscan2
- CCDC71 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs755916138, COSV100422486, COSV58910641; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC88A | c.3152T>C p.V1051A | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99711349; called by muse, mutect2
- CCNA1 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs754694176, COSV99715006; called by muse, mutect2, varscan2
- CCNG2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100313375; called by muse, mutect2, varscan2
- CCT8L2 | c.1657C>A p.L553I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.031); catalogued as rs1447379647, COSV100743220; called by muse, mutect2, varscan2
- CCT8L2 | c.628G>A p.G210R | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769261313, COSV63463005, COSV63463552; called by muse, mutect2, varscan2
- CCT8L2 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.044); catalogued as rs751694255, COSV100742894, COSV100743223; called by mutect2, varscan2
- CD163L1 | c.2686+1del p.X896_splice | Splice Site (DEL) | VAF 19/76 reads (25%) | catalogued as CS153145; called by mutect2, pindel, varscan2
- CD163L1 | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.301); catalogued as rs746544481, COSV100550802; called by muse, mutect2, varscan2
- CD1A | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.724); catalogued as rs1320058134, COSV99192650; called by muse, mutect2, varscan2
- CD276 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs780867163, COSV100573489; called by muse, mutect2, varscan2
- CDC45 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs913329845, COSV99597010; called by muse, mutect2, varscan2
- CDH1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs748086082, COSV99932788; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH16 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs565441011, COSV100234307; called by muse, mutect2, varscan2
- CDH22 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs867708490, COSV100953000; called by muse, mutect2, varscan2
- CDH23 | c.4805T>C p.L1602P | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99824362; called by muse, mutect2, varscan2
- CDH8 | c.2258G>C p.G753A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV100179910, COSV100184518, COSV54905279; called by muse, mutect2, varscan2
- CDKN2B | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52805270; called by muse, mutect2, varscan2
- CDON | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs773419494, COSV54997108; called by muse, mutect2, varscan2
- CEBPA | c.869A>T p.E290V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100204759; called by muse, mutect2, varscan2
- CELSR2 | c.4295C>T p.A1432V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1557731551, COSV99604943; called by muse, mutect2
- CEP350 | c.4373T>C p.L1458S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100855403; called by muse, mutect2, varscan2
- CERCAM | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs143495365; called by muse, mutect2, varscan2
- CES2 | c.1466A>C p.K489T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100399471; called by muse, mutect2, varscan2
- CFAP74 | c.1480C>T p.R494W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1380870743, COSV54564656; called by muse, mutect2, varscan2
- CFAP91 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs374383735; called by muse, mutect2, varscan2
- CFH | c.3133+2T>A p.X1045_splice | Splice Site (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100810330; called by muse, mutect2, varscan2
- CGNL1 | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99849329; called by muse, mutect2, varscan2
- CHD1 | c.4757G>A p.R1586H | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.976); catalogued as COSV99400033; called by muse, mutect2, varscan2
- CHD6 | c.4756A>G p.I1586V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs3746542, COSV100951397; called by muse, mutect2, varscan2
- CHRNA1 | c.367dup p.I123Nfs*17 (on ENST00000261007 / NM_001039523.3; = p.I98Nfs*17 on NM_000079.4) | Frame Shift Ins (INS) | VAF 29/101 reads (29%) | catalogued as rs753250273; called by mutect2, varscan2
- CHST7 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV52100545; called by muse, mutect2, varscan2
- CKAP2L | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs530137704, COSV100198829; called by muse, mutect2, varscan2
- CLC | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV55686059, COSV99695701; called by muse, mutect2, varscan2
- CLCA4 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753163783, COSV99760880; called by muse, mutect2, varscan2
- CLCF1 | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV100425721; called by muse, mutect2, varscan2
- CLEC14A | c.1143T>G p.N381K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as COSV100643689; called by muse, mutect2, varscan2
- CLEC18C | c.154C>A p.L52I | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV100032260; called by muse, mutect2, varscan2
- CLEC4F | c.740T>C p.L247S | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1553396136, COSV99714072; called by muse, mutect2, varscan2
- CLP1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295194077, COSV100239964; called by muse, mutect2, varscan2
- CNTN3 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 53/169 reads (31%) | catalogued as COSV55175097; called by muse, mutect2, varscan2
- CNTNAP2 | c.3250A>T p.S1084C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100673772; called by muse, mutect2, varscan2
- CNTNAP5 | c.1789C>T p.Q597* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV101444359, COSV70482374; called by muse, mutect2, varscan2
- CNTRL | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV99444175; called by muse, mutect2, varscan2
- CNTROB | c.1849C>T p.R617W | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368903729; called by muse, mutect2, varscan2
- COL11A1 | c.3001G>T p.A1001S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100618295; called by muse, mutect2, varscan2
- COL14A1 | c.4204C>T p.R1402* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs776498858, COSV52846274; called by muse, mutect2, varscan2
- COL16A1 | c.3061G>T p.G1021C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99595713; called by muse, mutect2, varscan2
- COL19A1 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100507719; called by muse, mutect2, varscan2
- COL1A2 | c.486G>T p.Q162H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99801429; called by muse, mutect2, varscan2
- COL22A1 | c.3835G>T p.G1279* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV57328049; called by muse, mutect2, varscan2
- COL3A1 | c.469T>A p.S157T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV100483885, COSV58592768; called by muse, mutect2, varscan2
- COL5A1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.096); catalogued as rs770173348, COSV65672484; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.5263G>A p.A1755T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.245); catalogued as rs776748227, COSV65664867, COSV65666442; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL5A2 | c.1010C>A p.P337Q | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV100880932, COSV66409120; called by muse, mutect2, varscan2
- COPG2 | c.678G>T p.Q226H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100449747; called by muse, mutect2, varscan2
- CPA5 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs782164665, COSV100812494; called by muse, mutect2, varscan2
- CPSF7 | c.469G>A p.V157M (on ENST00000394888 / NM_001136040.4; = p.V200M on NM_024811.4) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100467692; called by muse, mutect2, varscan2
- CRELD2 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100078358; called by muse, mutect2, varscan2
- CRMP1 | c.1685dup p.G563Wfs*19 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | catalogued as rs1161942169; called by mutect2, varscan2
- CSNK1D | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99484830; called by muse, mutect2, varscan2
- CSPG5 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV99274306; called by muse, mutect2, varscan2
- CTNNA3 | c.2542T>C p.W848R | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101041703; called by muse, mutect2, varscan2
- CTNNB1 | c.1005del p.K335Nfs*10 | Frame Shift Del (DEL) | VAF 27/94 reads (29%) | catalogued as COSV62718504; called by mutect2, pindel, varscan2
- CTNNB1 | c.1958C>A p.T653K | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100846547, COSV62708232; called by muse, varscan2
- CTNND1 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.92); catalogued as rs552330982, COSV100650322; called by muse, mutect2, varscan2
- CTNND1 | c.2091G>A p.T697= (on ENST00000399050 / NM_001085458.2; = p.T691= on NM_001331.3) | Splice Region (SNP) | VAF 18/56 reads (32%) | catalogued as COSV62385655; called by muse, mutect2, varscan2
- CTSV | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs754510545, COSV99414458; called by muse, mutect2, varscan2
- CTSW | c.446del p.N149Tfs*14 | Frame Shift Del (DEL) | VAF 11/45 reads (24%) | catalogued as rs1156665339; called by mutect2, pindel, varscan2
- CYFIP2 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs1239470942, COSV100557950; called by muse, mutect2, varscan2
- CYP1A2 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.556); catalogued as COSV100673950; called by muse, mutect2, varscan2
- CYP26C1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV99592632; called by muse, mutect2, varscan2
- DBX1 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV99910357; called by muse, mutect2, varscan2
- DCHS1 | c.2981G>A p.R994H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs751706722, COSV100202703, COSV55035951; called by muse, varscan2
- DCST1 | c.1408C>G p.L470V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.355); catalogued as rs202162660, COSV55063674; called by muse, mutect2, varscan2
- DCT | c.555del p.F185Lfs*14 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs762895555; called by mutect2, pindel, varscan2
- DDHD1 | c.662A>G p.K221R (on ENST00000323669; = p.K418R on NM_030637.3) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100080218, COSV60356881; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs766714372; called by mutect2, varscan2
- DEPDC1B | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs531674599, COSV54009821; called by muse, mutect2, varscan2
- DFFB | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100220921; called by muse, mutect2, varscan2
- DGCR2 | c.1562del p.P521Lfs*128 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs747144238; called by mutect2, pindel, varscan2
- DIP2C | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99794056; called by muse, mutect2, varscan2
- DIPK1B | c.400del p.R134Gfs*22 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as COSV63038346; called by mutect2, pindel
- DISP1 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.739); catalogued as rs749431977, COSV52659494; called by muse, mutect2, varscan2
- DISP3 | c.1341del p.T448Qfs*71 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as COSV53825227; called by mutect2, pindel, varscan2
- DLAT | c.342del p.E115Rfs*10 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | catalogued as rs782180715; called by mutect2, varscan2
- DLGAP2 | c.984del p.D329Tfs*31 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | catalogued as COSV70098144; called by mutect2, pindel, varscan2
- DMRTA1 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs761323285, COSV100364926; called by muse, mutect2, varscan2
- DMTN | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs377647942; called by muse, mutect2, varscan2
- DMXL2 | c.7140G>C p.M2380I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as rs1269304375, COSV51855229, COSV99198834; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF2 | c.2232G>T p.Q744H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100024264; called by muse, mutect2, varscan2
- DNAH3 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs541602132, COSV54509013; called by muse, mutect2, varscan2
- DNAH5 | c.8236G>T p.V2746L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773643407, COSV99455312; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB7 | c.884del p.K295Rfs*25 | Frame Shift Del (DEL) | VAF 50/76 reads (66%) | catalogued as rs768619916; called by mutect2, varscan2
- DNAJC13 | c.3215C>T p.P1072L | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754178638, COSV99608314; called by muse, mutect2, varscan2
- DNM1L | c.1556G>T p.R519M | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as COSV99846542; called by muse, mutect2, varscan2
- DOCK2 | c.1166A>G p.D389G | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99916126; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPP3 | c.1927G>T p.G643W | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); catalogued as COSV100855784; called by muse, mutect2, varscan2
- DSC1 | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99938393; called by muse, mutect2, varscan2
- DSC2 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99199928; called by muse, mutect2, varscan2
- DSCAML1 | c.3672C>A p.S1224R (on ENST00000321322; = p.S1164R on NM_020693.4) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV100357441; called by muse, mutect2, varscan2
- DVL1 | c.1288G>T p.E430* (on ENST00000378888 / NM_001330311.2; = p.E405* on NM_004421.3) | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100229932; called by muse, mutect2, varscan2
- DYNC2H1 | c.4844A>G p.Q1615R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs765350303, COSV100519991; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 32/42 reads (76%) | catalogued as rs369293935; called by mutect2, varscan2
- ECE1 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as rs867547949, COSV51663549; called by muse, mutect2, varscan2
- ECT2L | c.2028+2T>C p.X676_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as rs776602596, COSV100872219; called by muse, mutect2, varscan2
- EDEM2 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs775554503, COSV63259512; called by muse, mutect2, varscan2
- EDNRA | c.676A>G p.M226V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs543490260, COSV100163690; called by muse, mutect2, varscan2
- EEA1 | c.2431del p.I811Sfs*2 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs776707160; called by mutect2, varscan2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EIF4G1 | c.1305del p.T436Pfs*86 (on ENST00000346169 / NM_198241.3; = p.T240Pfs*86 on NM_004953.5) | Frame Shift Del (DEL) | VAF 49/157 reads (31%) | catalogued as COSV104407217; called by mutect2, pindel, varscan2
- ELAVL1 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1156860701, COSV60967577; called by muse, mutect2, varscan2
- ELAVL4 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100836952; called by muse, mutect2, varscan2
- ELF1 | c.965A>T p.N322I | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99523390; called by muse, mutect2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 31/78 reads (40%) | catalogued as rs759858342; called by mutect2, varscan2
- EN2 | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763911920, COSV52083595; called by muse, mutect2, varscan2
- ENAM | c.395dup p.P133Afs*13 | Frame Shift Ins (INS) | VAF 29/93 reads (31%) | catalogued as rs1339687136; called by mutect2, pindel, varscan2
- ENDOD1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99566897; called by muse, mutect2, varscan2
- EP300 | c.6970dup p.H2324Pfs*55 | Frame Shift Ins (INS) | VAF 16/54 reads (30%) | catalogued as rs754418509; called by mutect2, varscan2
- EPAS1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs776459473, COSV55384997; called by muse, mutect2, varscan2
- EPHA5 | c.2392C>A p.H798N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901833; called by muse, mutect2, varscan2
- EPHA8 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV99385889; called by muse, mutect2, varscan2
- EPHA8 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs539448650, COSV51266521; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 42/60 reads (70%) | catalogued as rs768793415; called by mutect2, varscan2
- ERMN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 38/114 reads (33%) | catalogued as rs1469712056, COSV101263012, COSV68075619; called by muse, mutect2, varscan2
- ESCO1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs764998855, COSV99332677; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs775950025; called by mutect2, varscan2
- EXOSC10 | c.2625C>T p.D875= (on ENST00000376936 / NM_001001998.3; = p.D850= on NM_002685.4) | Splice Region (SNP) | VAF 22/76 reads (29%) | catalogued as rs1249831171, COSV100442983; called by muse, varscan2
- EYA2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs202115929; called by muse, mutect2, varscan2
- FAM20B | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs892527665, COSV55380216; called by muse, mutect2, varscan2
- FAM47B | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV100264702; called by muse, mutect2, varscan2
- FAM53B | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV99785085; called by muse, mutect2, varscan2
- FAM83H | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782792314, COSV101187091; called by muse, mutect2, varscan2
- FASN | c.126G>A p.A42= | Splice Region (SNP) | VAF 22/57 reads (39%) | catalogued as rs201369909, COSV100148437; called by muse, mutect2, varscan2
- FASTKD5 | c.796dup p.S266Ffs*2 | Frame Shift Ins (INS) | VAF 21/73 reads (29%) | catalogued as rs1436077092; called by mutect2, pindel, varscan2
- FAT2 | c.10853A>G p.Y3618C | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV99944385; called by muse, mutect2, varscan2
- FAT2 | c.9763G>A p.V3255M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV55832340; called by muse, mutect2, varscan2
- FAT3 | c.10841G>C p.G3614A | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99972176; called by muse, mutect2, varscan2
- FAT4 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV67887545; called by muse, mutect2, varscan2
- FAT4 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs989762568, COSV101272922; called by muse, mutect2, varscan2
- FBN2 | c.4780A>G p.N1594D | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.253); catalogued as COSV99331311; called by muse, mutect2, varscan2
- FBXO16 | c.721A>G p.M241V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100672513; called by muse, mutect2, varscan2
- FBXO24 | c.527G>A p.R176H (on ENST00000241071 / NM_033506.3; = p.R214H on NM_012172.5) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs768402143, COSV53827718; called by muse, mutect2, varscan2
- FBXO38 | c.2675G>A p.R892H (on ENST00000340253 / NM_205836.3; = p.R817H on NM_030793.5) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs183483408, COSV57033345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCGR1A | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1161084692, COSV100977284; called by muse, mutect2, varscan2
- FERMT3 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.695); catalogued as COSV99656915; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 31/66 reads (47%) | catalogued as rs748969702; called by mutect2, varscan2
- FGFR1 | c.853C>T p.P285S (on ENST00000447712 / NM_023110.3; = p.P283S on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV58333300; called by muse, mutect2, varscan2
- FGG | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100272129; called by muse, mutect2, varscan2
- FIGN | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as rs750122544, COSV100292303; called by muse, mutect2, varscan2
- FILIP1 | c.2419A>T p.T807S | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99386346; called by muse, mutect2, varscan2
- FLNA | c.5381T>C p.V1794A (on ENST00000369850 / NM_001110556.2; = p.V1786A on NM_001456.3) | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV100775370; called by muse, mutect2, varscan2
- FLT4 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs148392893, COSV56112199, COSV56119760; called by muse, mutect2, varscan2
- FMNL1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.611); catalogued as COSV100057059; called by muse, mutect2, varscan2
- FNDC1 | c.5165C>T p.P1722L | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99797259; called by muse, mutect2, varscan2
- FNIP1 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs148075882; called by muse, mutect2, varscan2
- FOLR3 | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs371900505; called by muse, mutect2, varscan2
- FOXA3 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs543169864, COSV56217586; called by muse, mutect2, varscan2
- FOXRED2 | c.481C>A p.H161N | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs377328230; called by muse, mutect2, varscan2
- FREM2 | c.5916G>C p.E1972D | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54831002; called by muse, mutect2, varscan2
- FRMD4B | c.561A>G p.E187= | Splice Region (SNP) | VAF 3/9 reads (33%) | catalogued as COSV101273683; called by muse, mutect2
- FRYL | c.6436C>T p.H2146Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99978468; called by muse, mutect2, varscan2
- FUCA2 | c.1297T>C p.W433R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99136291; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- GAB2 | c.1562G>A p.R521Q (on ENST00000361507 / NM_080491.3; = p.R483Q on NM_012296.3) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as COSV60867891; called by muse, mutect2, varscan2
- GAB3 | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.307); catalogued as COSV100850720; called by muse, mutect2, varscan2
- GABARAPL2 | c.263+2T>C p.X88_splice | Splice Site (SNP) | VAF 26/93 reads (28%) | catalogued as COSV99231206; called by muse, mutect2, varscan2
- GABBR2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1214384447, COSV99411941; called by muse, mutect2, varscan2
- GABRD | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781426402, COSV101059563, COSV101059590; called by muse, mutect2, varscan2
- GADD45G | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); catalogued as rs1346544074, COSV99378721; called by muse, mutect2, varscan2
- GALNT17 | c.367T>C p.Y123H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs780111888, COSV100356696; called by muse, mutect2, varscan2
- GALNT5 | c.2066A>G p.D689G | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99375664; called by muse, mutect2, varscan2
- GBA3 | c.912dup p.A305Cfs*29 | Frame Shift Ins (INS) | VAF 6/22 reads (27%) | catalogued as rs776182136; called by mutect2, varscan2
- GCN1 | c.1192+2T>C p.X398_splice | Splice Site (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100326204; called by muse, mutect2, varscan2
- GFPT2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202097862; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 14/32 reads (44%) | catalogued as rs763147690; called by mutect2, varscan2
- GIGYF2 | c.3807G>A p.M1269I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101004661; called by muse, mutect2, varscan2
- GJC3 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs767367390, COSV100458551; called by muse, mutect2, varscan2
- GK2 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV62627654; called by muse, mutect2, varscan2
- GLI3 | c.4369G>C p.A1457P | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV101230137; called by muse, mutect2, varscan2
- GLIS3 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs770992784, COSV60927277; called by muse, mutect2
- GLTP | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1271835634, COSV100570423; called by muse, mutect2, varscan2
- GM2A | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs747270491, COSV100852062; called by muse, mutect2, varscan2
- GMFG | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV99453536; called by muse, mutect2, varscan2
- GON4L | c.1644A>C p.E548D | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV99676087; called by muse, mutect2, varscan2
- GP1BA | c.1480dup p.T494Nfs*4 | Frame Shift Ins (INS) | VAF 25/57 reads (44%) | catalogued as rs759573909; called by mutect2, varscan2
- GPD1L | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1042900556, COSV56991036; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPD1L | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV56991481; called by muse, varscan2
- GPN3 | c.679A>G p.M227V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs900012159, COSV99959614; called by muse, mutect2, varscan2
- GPR21 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.079); catalogued as COSV101016538; called by muse, mutect2, varscan2
- GPR26 | c.586C>T p.L196F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs529569788, COSV99501162; called by muse, mutect2, varscan2
- GPRASP2 | c.2342T>A p.I781N | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV100177006; called by muse, mutect2, varscan2
- GREB1 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779065905, COSV52190944; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 27/83 reads (33%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.2516C>T p.A839V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as COSV66149105; called by muse, mutect2, varscan2
- GRIK3 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs777392880; called by muse, varscan2
- GRIK3 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1398285941, COSV100902423; called by muse, mutect2, varscan2
- GRIK5 | c.947G>A p.S316N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV99491493; called by muse, mutect2, varscan2
- GRIN2A | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1211198789, COSV58057391; called by muse, mutect2, varscan2
- GRK3 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV60797783, COSV60798709; called by muse, mutect2, varscan2
- GRM1 | c.2734C>T p.R912C | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV51171747, COSV51300307; called by muse, mutect2, varscan2
- GRM3 | c.1894T>G p.F632V | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV100862987; called by muse, mutect2, varscan2
- GRM4 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs140826793, COSV65214976; called by muse, mutect2, varscan2
- GSC | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99450436; called by muse, mutect2, varscan2
- GTF2IRD2B | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.007); catalogued as COSV100441313; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs750792116; called by mutect2, varscan2
- GUSB | c.1001G>A p.S334N | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100512802; called by muse, mutect2, varscan2
- GXYLT1 | c.1282del p.S428Vfs*2 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as COSV55133567; called by mutect2, pindel, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs750293240, COSV55140417; called by mutect2, varscan2
- H2AC21 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100480228; called by muse, mutect2, varscan2
- H3C7 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 72/90 reads (80%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV55100559, COSV99769315; called by muse, mutect2, varscan2
- H6PD | c.1651C>T p.R551* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs760131543, COSV101072496; called by muse, mutect2, varscan2
- HECTD1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101237557; called by muse, mutect2
- HECTD2 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV99979063; called by muse, mutect2, varscan2
- HEPACAM2 | c.1320A>C p.Q440H (on ENST00000394468 / NM_001039372.4; = p.Q428H on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV59064573; called by muse, mutect2, varscan2
- HEPHL1 | c.1913G>T p.C638F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100244556; called by muse, mutect2, varscan2
- HES6 | c.361G>T p.V121F | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs1331695556, COSV99612714; called by muse, mutect2, varscan2
- HID1 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs759385862, COSV100586120; called by muse, varscan2
- HIPK2 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as rs748728818, COSV100702640; called by muse, mutect2, varscan2
- HIVEP1 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 93/130 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.373); catalogued as rs370383342; called by muse, mutect2, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 8/39 reads (21%) | catalogued as rs199474609; called by mutect2, varscan2
- HMCES | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV101077413; called by muse, mutect2, varscan2
- HOOK3 | c.1233C>T p.D411= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as rs188582867, COSV56882933; called by muse, mutect2, varscan2
- HOXA3 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.104); catalogued as COSV100415754; called by muse, mutect2, varscan2
- HSPA4 | c.1709C>A p.A570E | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.812); catalogued as COSV100507928; called by muse, mutect2, varscan2
- HUWE1 | c.9925C>T p.R3309C | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53356317; called by muse, mutect2, varscan2
- HYDIN | c.10140G>T p.K3380N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV101158887; called by muse, mutect2, varscan2
- HYOU1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101345703; called by muse, mutect2
- IARS1 | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | catalogued as rs745932544, COSV65115626, COSV65116757; called by muse, mutect2, varscan2
- IBA57 | c.681C>T p.G227= | Splice Region (SNP) | VAF 17/54 reads (31%) | catalogued as rs1287946008, COSV100812804; called by muse, mutect2, varscan2
- ICE1 | c.5263A>G p.M1755V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs762389377, COSV99665965; called by muse, varscan2
- ICOS | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as COSV100320480; called by muse, mutect2, varscan2
- IFFO1 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.387); catalogued as rs768586699, COSV100351412; called by mutect2, varscan2
- IFI16 | c.1685C>G p.T562S (on ENST00000295809 / NM_001364867.2; = p.T506S on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV99856920; called by muse, mutect2, varscan2
- IFIT1 | c.1007del p.K336Sfs*9 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | catalogued as rs1202143274; called by mutect2, pindel, varscan2
- IFIT5 | c.1006_1007del p.M336Vfs*14 | Frame Shift Del (DEL) | VAF 25/90 reads (28%) | catalogued as rs1372993606; called by mutect2, pindel, varscan2
- IGF1 | c.109C>A p.L37M | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV100191474; called by muse, mutect2, varscan2
- IGF2BP1 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781338712, COSV51730358; called by muse, mutect2, varscan2
- IGF2R | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs746024088, COSV63628877; called by muse, mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGFL2 | c.172G>A p.V58M (on ENST00000377693 / NM_001135113.2; = p.V69M on NM_001002915.2) | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs367624938; called by muse, mutect2, varscan2
- IGHA1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs370272298; called by muse, mutect2, varscan2
- IGKV1-8 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); catalogued as rs974728367; called by muse, mutect2, varscan2
- IGSF1 | c.1957A>G p.S653G | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT tolerated (0.19); PolyPhen benign (0.171); catalogued as COSV100812440; called by muse, mutect2, varscan2
- IGSF9B | c.2371C>T p.R791* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as rs1251265858, COSV100318613; called by muse, mutect2
- IKBIP | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1368575262, COSV100141927; called by muse, mutect2, varscan2
- IL12B | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1033790517, COSV99180388; called by muse, mutect2, varscan2
- IMP4 | c.577_579del p.S193del | In Frame Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs746721288; called by pindel, varscan2
- INSYN2A | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV99733449; called by muse, mutect2
- INTS3 | c.3121A>G p.S1041G | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99670228; called by muse, mutect2, varscan2
- IPO7 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs750326745, COSV65684261; called by muse, varscan2
- IRF2BP2 | c.1692G>T p.W564C | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100784422; called by muse, mutect2, varscan2
- ITIH1 | c.1967G>A p.S656N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as COSV99835679; called by muse, varscan2
- ITPR1 | c.2998C>T p.R1000* (on ENST00000354582; = p.R985* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs1436270318, COSV56988176; called by muse, mutect2, varscan2
- ITPRID2 | c.3467C>T p.T1156M | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as rs145518704; called by muse, mutect2, varscan2
- JPH1 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV100646827; called by muse, mutect2, varscan2
- JPH1 | c.1475C>T p.A492V | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs377278223; called by muse, mutect2, varscan2
- KALRN | c.1781C>T p.A594V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV53755784; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNJ16 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.338); catalogued as COSV99388828; called by muse, mutect2, varscan2
- KCNQ4 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); catalogued as COSV100714449; called by muse, mutect2
- KCNQ4 | c.1770del p.D593Tfs*23 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as COSV100714274, COSV61272307; called by mutect2, pindel, varscan2
- KCNT1 | c.2743G>T p.A915S (on ENST00000488444; = p.A934S on NM_020822.3) | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as CM129794, COSV53703025, COSV99706966; called by muse, mutect2, varscan2
- KCNV2 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs140144634; called by muse, mutect2, varscan2
- KDM2B | c.3016del p.R1006Gfs*37 | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | catalogued as rs1555288650, COSV65639291; called by mutect2, varscan2
- KDM2B | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100997701; called by muse, mutect2, varscan2
- KDM3B | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 58/186 reads (31%) | catalogued as COSV100070336; called by muse, mutect2, varscan2
- KDM6B | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV99642480; called by muse, mutect2, varscan2
- KIAA1217 | c.4179G>T p.Q1393H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100287436; called by muse, mutect2, varscan2
- KIAA1549L | c.1028C>A p.P343Q (on ENST00000321505; = p.P640Q on NM_012194.3) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV99684692; called by muse, mutect2, varscan2
- KIAA1549L | c.3256C>T p.R1086C (on ENST00000321505; = p.R1383C on NM_012194.3) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368066574; called by muse, mutect2, varscan2
- KIAA1549L | c.4150T>C p.S1384P (on ENST00000321505; = p.S1681P on NM_012194.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); catalogued as COSV100382584; called by muse, mutect2, varscan2
- KIAA1614 | c.3433G>A p.G1145S | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760919913, COSV100799919; called by muse, mutect2, varscan2
- KIAA1958 | c.593T>G p.V198G | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100516552; called by muse, mutect2, varscan2
- KIAA2013 | c.1049_1051del p.K350del | In Frame Del (DEL) | VAF 23/88 reads (26%) | catalogued as rs750737879; called by pindel, varscan2
- KIF17 | c.967C>A p.L323I | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV99929940; called by muse, mutect2, varscan2
- KIF21A | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750947190, COSV100735758, COSV62769898; called by muse, mutect2, varscan2
- KIF21B | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100145263; called by muse, mutect2, varscan2
- KIF22 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99361556; called by muse, mutect2, varscan2
- KIF26B | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs767081137, COSV69469139; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KLC1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs1278257675, COSV99872003; called by muse, mutect2, varscan2
- KLF5 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.486); catalogued as COSV100890595; called by muse, mutect2, varscan2
- KLHL2 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99900497; called by muse, mutect2, varscan2
- KLHL22 | c.1198T>C p.Y400H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV100186309; called by muse, mutect2, varscan2
- KLHL31 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV100911865; called by muse, mutect2, varscan2
- KRT25 | c.1347C>A p.S449R | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100380125; called by muse, mutect2, varscan2
- KRT31 | c.948C>A p.S316R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs201100680; called by muse, mutect2
- KRT71 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV99922442; called by muse, mutect2, varscan2
- KRTAP5-10 | c.260G>T p.C87F | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV100924173; called by muse, mutect2, varscan2
- LAMA1 | c.6271T>G p.L2091V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101057976; called by muse, mutect2, varscan2
- LAMA2 | c.4205G>A p.R1402H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs144830879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LARGE1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746251069, COSV61665276; called by muse, mutect2, varscan2
- LARGE2 | c.1684C>T p.R562C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs576172696, COSV99139660; called by muse, mutect2, varscan2
- LARP4B | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV100295774; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 32/83 reads (39%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LCN1 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs138245590; called by muse, mutect2, varscan2
- LDHA | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.161); catalogued as rs760172008, COSV99908479; called by muse, mutect2, varscan2
- LEF1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99490116; called by muse, mutect2, varscan2
- LIG4 | c.1693G>A p.V565I | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.34); catalogued as rs140584260; called by muse, mutect2, varscan2
- LLGL2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144919589; called by muse, mutect2, varscan2
- LMO7 | c.1740del p.E582Nfs*33 (on ENST00000357063; = p.E312Nfs*33 on NM_015842.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as COSV58544634; called by mutect2, pindel, varscan2
- LRP1 | c.3293A>G p.E1098G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.255); catalogued as COSV99677676; called by muse, mutect2, varscan2
- LRP1B | c.12266A>C p.D4089A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101262108; called by muse, mutect2, varscan2
- LRP6 | c.2840T>A p.M947K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99744748; called by muse, mutect2
- LRRC14 | c.311G>A p.S104N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1466161863, COSV99468385; called by muse, mutect2, varscan2
- LRRC37A | c.3573G>T p.Q1191H | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.276); catalogued as COSV100208306; called by muse, mutect2, varscan2
- LRRN4 | c.1610_1612del p.E537del | In Frame Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs758006380; called by pindel, varscan2
- LSAMP | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577289191, COSV61277398; called by muse, mutect2, varscan2
- LYPD2 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs766307085, COSV63649396, COSV63649517; called by muse, mutect2, varscan2
- LYPLA1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV57604553; called by muse, mutect2
- LYST | c.6713G>A p.R2238Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs1035232599, COSV67708723; called by muse, mutect2, varscan2
- LZTS2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.585); catalogued as COSV100932312; called by muse, mutect2, varscan2
- LZTS2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756282708, COSV100932186, COSV100932313; called by muse, mutect2, varscan2
- MAN1C1 | c.1296del p.L433* | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs759630213; called by mutect2, pindel
- MAN2A1 | c.1916del p.N639Ifs*2 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs758700583; called by mutect2, pindel, varscan2
- MAN2B2 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.728); catalogued as rs756714926, COSV99578234; called by muse, mutect2, varscan2
- MAP1B | c.3625C>T p.P1209S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99703031; called by muse, mutect2, varscan2
- MAP1B | c.5416G>A p.A1806T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.101); catalogued as COSV99703032; called by muse, varscan2
- MAP3K9 | c.3127G>A p.V1043I (on ENST00000554752 / NM_001284230.1; = p.V1057I on NM_033141.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV101173795; called by muse, mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs761388884; called by mutect2, pindel, varscan2
- MAPK12 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750761400, COSV99299751; called by muse, mutect2, varscan2
- MAPKBP1 | c.2794C>T p.R932* (on ENST00000456763 / NM_001128608.2; = p.R926* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 37/82 reads (45%) | catalogued as COSV52963266, COSV99529945; called by muse, mutect2, varscan2
- MARVELD2 | c.1289del p.P430Qfs*9 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs1283422805; called by mutect2, pindel, varscan2
- MATN3 | c.1159del p.T387Hfs*10 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs1203662025; called by mutect2, pindel, varscan2
- MBD6 | c.2345dup p.A783Sfs*10 | Frame Shift Ins (INS) | VAF 17/53 reads (32%) | catalogued as rs746267361; called by mutect2, varscan2
- MCM2 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as COSV99413546; called by muse, mutect2, varscan2
- MCM4 | c.2578G>A p.V860M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as rs142208176, COSV100031193; called by muse, mutect2, varscan2
- MCTP2 | c.2615G>A p.R872Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs141407505; called by muse, mutect2, varscan2
- ME3 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100042565; called by muse, mutect2, varscan2
- MECOM | c.15C>A p.D5E (on ENST00000468789 / NM_001105078.4; = p.D193E on NM_004991.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99245744; called by muse, mutect2, varscan2
- MEMO1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.278); catalogued as COSV99704834; called by muse, mutect2, varscan2
- METTL21A | c.392G>C p.S131T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.084); catalogued as COSV99777796; called by muse, mutect2
- MFAP3L | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as rs191559223; called by muse, mutect2, varscan2
- MFSD9 | c.1326del p.S443Afs*6 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs769987847; called by mutect2, pindel, varscan2
- MGAT2 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs781499653, COSV100023665; called by muse, mutect2, varscan2
- MIB1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs1235146165, COSV55089793; called by muse, mutect2, varscan2
- MICAL2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV99818533; called by muse, mutect2
- MIEF2 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100493852; called by muse, mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs751465048; called by mutect2, varscan2
- MMP13 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as rs1021948203, COSV52824435; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MMRN2 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs1021062847, COSV100922681; called by muse, mutect2, varscan2
- MOS | c.538A>G p.K180E | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.411); catalogued as rs773486880, COSV100323056; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1916C>T p.A639V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.773); catalogued as COSV99732984; called by muse, mutect2, varscan2
- MPST | c.394C>A p.L132I (on ENST00000341116 / NM_001369904.2; = p.L152I on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV100353472; called by muse, mutect2, varscan2
- MPZ | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.865); catalogued as rs775361544, CM1211221, COSV100337988; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRNIP | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV99481853; called by muse, mutect2, varscan2
- MROH2B | c.4114dup p.I1372Nfs*26 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | catalogued as rs756600463; called by mutect2, varscan2
- MTBP | c.267T>G p.F89L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as COSV100012644; called by muse, mutect2, varscan2
- MTCL1 | c.2677G>A p.V893M (on ENST00000306329 / NM_001378206.1; = p.V533M on NM_015210.4) | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as COSV100095840; called by muse, mutect2, varscan2
- MTOR | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs1012774947, COSV100816767; called by muse, mutect2, varscan2
- MUC4 | c.2480C>T p.T827M | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs750131166, COSV100642589; called by muse, mutect2, varscan2
- MUC5B | c.6091G>A p.G2031R | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs532066756; called by muse, varscan2
- MUC6 | c.4948A>T p.T1650S | Missense Mutation (SNP) | VAF 54/452 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.914); catalogued as COSV101424865, COSV70141171, COSV70144684; called by muse, varscan2
- MUC6 | c.2857G>A p.V953M | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs527440972, COSV101424866; called by muse, mutect2, varscan2
- MXRA5 | c.2467G>A p.A823T | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV54228293; called by muse, mutect2
- MYBPC3 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.296); catalogued as rs775837337, COSV57026941; called by muse, mutect2, varscan2
- MYCBP2 | c.1054G>A p.G352R (on ENST00000357337; = p.G390R on NM_015057.5) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100632331; called by muse, mutect2, varscan2
- MYH11 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 6/97 reads (6%) | catalogued as COSV100260512; called by muse, mutect2
- MYH14 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs770972513, COSV51820792; called by muse, mutect2, varscan2
- MYH14 | c.5380C>T p.R1794C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751422907, COSV51819684; called by muse, mutect2, varscan2
- MYH7 | c.2908G>A p.A970T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1446657813, COSV62520567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH8 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV101238964; called by muse, mutect2, varscan2
- MYO10 | c.4990G>A p.E1664K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs773910122, COSV99946535; called by muse, mutect2, varscan2
- MYO15A | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.439); catalogued as COSV99234798; called by muse, mutect2, varscan2
- MYO16 | c.2642C>T p.A881V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs771546307, COSV99194899; called by muse, mutect2, varscan2
- MYO1F | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs772331130, COSV57797105; called by muse, mutect2, varscan2
- MYOCD | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58496941; called by muse, mutect2, varscan2
- MYOM2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as rs201125974, COSV50708722; called by muse, mutect2, varscan2
- MYPOP | c.1139del p.P380Hfs*26 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs757587344; called by mutect2, pindel, varscan2
- NAA16 | c.1890A>T p.E630D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769875149, COSV65127991; called by muse, mutect2, varscan2
- NAGLU | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1367528849, COSV56795733, COSV99864428; called by muse, mutect2, varscan2
- NALCN | c.3933T>G p.F1311L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99218374; called by muse, mutect2, varscan2
- NAV3 | c.2476A>G p.I826V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as COSV99896588; called by muse, mutect2, varscan2
- NCCRP1 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs771330902, COSV59212355; called by muse, varscan2
- NCKAP5 | c.3580A>G p.K1194E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV100494730; called by muse, mutect2, varscan2
- NCOR2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs776360455, COSV62301493; called by muse, mutect2, varscan2
- NDUFAF1 | c.71T>C p.L24S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99531612; called by muse, mutect2
- NEFL | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as COSV55336237; called by muse, mutect2, varscan2
- NEK8 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV99262374; called by muse, mutect2, varscan2
- NEK8 | c.886A>G p.R296G | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs756135134, COSV99262376; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 38/110 reads (35%) | catalogued as rs759081520; called by mutect2, varscan2
- NES | c.973A>G p.S325G | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100958027; called by muse, mutect2, varscan2
- NEUROD4 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670232; called by muse, mutect2, varscan2
- NF1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs1343309278, COSV62225224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFIB | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101100378; called by muse, mutect2, varscan2
- NFKBIZ | c.1123A>G p.S375G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100397288; called by muse, mutect2, varscan2
- NHLH1 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1361488624, COSV57484393; called by muse, mutect2, varscan2
- NID1 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV99938468; called by muse, mutect2, varscan2
- NISCH | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.456); catalogued as rs764100876, COSV100617276, COSV61902731; called by muse, mutect2, varscan2
- NKPD1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100521764; called by muse, mutect2, varscan2
- NKRF | c.1408T>A p.Y470N | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV100441943; called by muse, mutect2, varscan2
- NKX2-2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs778090576, COSV101010641; called by muse, varscan2
- NKX2-2 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV65820230; called by muse, varscan2
- NKX2-3 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60729259; called by muse, mutect2, varscan2
- NOMO1 | c.1378G>T p.G460W | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814955; called by mutect2, varscan2
- NOS3 | c.3488C>T p.T1163M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99872315; called by mutect2, varscan2
- NOTCH1 | c.3665T>C p.V1222A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV99492543; called by muse, mutect2, varscan2
- NPAS4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1471054323, COSV60648685, COSV60652980; called by muse, mutect2, varscan2
- NPS | c.257G>T p.R86I | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101219436; called by muse, mutect2, varscan2
- NR0B2 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV99575103; called by muse, mutect2, varscan2
- NR1D1 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.224); catalogued as rs200771218, COSV99225853; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs774343392; called by mutect2, varscan2
- NRXN1 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV68033383; called by muse, mutect2, varscan2
- NRXN3 | c.548G>A p.G183D (on ENST00000557594 / NM_001272020.2; = p.G815D on NM_004796.6) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822577; called by muse, mutect2, varscan2
- NSD1 | c.2765C>T p.T922M | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs753460351, COSV100729913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSF | c.1872G>T p.Q624H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56576614, COSV99834077; called by muse, mutect2, varscan2
- NT5C1B | c.746G>A p.R249H (on ENST00000359846 / NM_001199086.2; = p.R189H on NM_033253.4) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100409791; called by muse, mutect2, varscan2
- NTN1 | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99434060; called by muse, mutect2
- NUAK1 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777404; called by muse, mutect2, varscan2
- NUBP2 | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99236724; called by muse, mutect2, varscan2
- NUP210 | c.403del p.L135Wfs*3 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs762804106; called by mutect2, pindel, varscan2
- NUP85 | c.1934G>A p.R645Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs372841934; called by muse, mutect2, varscan2
- NUP93 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs146068835; called by muse, mutect2, varscan2
- NUP98 | c.4934G>A p.R1645H (on ENST00000359171 / NM_001365126.1; = p.R1628H on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs766404431, COSV100263665; called by muse, mutect2, varscan2
- NUTM2A | c.685del p.L229Sfs*146 | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | catalogued as rs1336711701; called by mutect2, pindel, varscan2
- ODF2L | c.1221dup p.Q408Tfs*6 (on ENST00000317336; = p.Q379Tfs*6 on NM_020729.3) | Frame Shift Ins (INS) | VAF 22/44 reads (50%) | catalogued as rs761049141; called by mutect2, varscan2
- OGDHL | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs780288193, COSV65104236; called by muse, mutect2, varscan2
- OLFM2 | c.692G>A p.W231* | Nonsense Mutation (SNP) | VAF 13/15 reads (87%) | catalogued as rs1321733537, COSV99322122; called by muse, mutect2, varscan2
- OR10G7 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as COSV100390111, COSV57867904; called by muse, mutect2, varscan2
- OR2B3 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs758560180, COSV101013870; called by muse, mutect2, varscan2
- OR2H1 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101009952; called by muse, mutect2, varscan2
- OR4L1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.034); catalogued as rs1398535138, COSV100235946; called by muse, mutect2, varscan2
- OR4M1 | c.654T>G p.Y218* | Nonsense Mutation (SNP) | VAF 44/245 reads (18%) | catalogued as COSV100270944, COSV100271569; called by muse, mutect2, varscan2
- OR51S1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100437602; called by muse, mutect2, varscan2
- OR52E2 | c.272T>A p.L91H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100384962; called by muse, mutect2, varscan2
- OR5H2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100788880; called by muse, mutect2, varscan2
- OR6C75 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.461); catalogued as COSV100595478; called by muse, mutect2, varscan2
- OR6K2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768885609, COSV100656781, COSV100656915; called by muse, mutect2, varscan2
- OSR2 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1247882502, COSV99882899; called by muse, mutect2, varscan2
- OTOGL | c.6630G>A p.W2210* (on ENST00000547103; = p.W2201* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100087904, COSV100088048; called by muse, mutect2, varscan2
- OTP | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100119925; called by muse, mutect2, varscan2
- P2RY8 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as rs1208023789, COSV101184223; called by muse, mutect2, varscan2
- PABPC3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201771028, COSV55801498; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1688A>G p.D563G (on ENST00000259318 / NM_001136562.3; = p.D794G on NM_007203.5) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1182126807, COSV99395885; called by muse, mutect2, varscan2
- PANX2 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1488640466, COSV50292514; called by muse, mutect2, varscan2
- PAPPA | c.985C>G p.Q329E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100073760, COSV100075654; called by muse, mutect2, varscan2
- PAQR4 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs566373345, COSV99234321; called by muse, mutect2, varscan2
- PARP1 | c.1771C>T p.R591C | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752905479, COSV64689863, COSV64692000; called by muse, mutect2, varscan2
- PARP14 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs761873665, COSV101506369; called by muse, mutect2, varscan2
- PARP8 | c.1202T>C p.L401S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); catalogued as COSV99893052; called by muse, mutect2, varscan2
- PCDH1 | c.3092G>A p.S1031N | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs774024986, COSV99747145; called by muse, mutect2, varscan2
- PCDH10 | c.360dup p.S121Lfs*13 | Frame Shift Ins (INS) | VAF 52/75 reads (69%) | catalogued as rs759095467; called by mutect2, varscan2
- PCDH10 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV52101304; called by muse, mutect2, varscan2
- PCDH15 | c.4567A>C p.K1523Q (on ENST00000617271 / NM_001142770.3; = p.K1511T on NM_001142769.3) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | PolyPhen benign (0.081); catalogued as COSV100905921; called by muse, mutect2
- PCDH19 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM162899, COSV55271064, COSV99721011; called by muse, mutect2, varscan2
- PCDH8 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.302); catalogued as COSV100132117; called by muse, mutect2, varscan2
- PCDHA12 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as rs1554169960, COSV56536855; called by muse, mutect2, varscan2
- PCDHA13 | c.2152T>C p.Y718H | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99170176; called by muse, mutect2, varscan2
- PCDHA4 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV63540466; called by muse, varscan2
- PCDHA7 | c.1645G>A p.V549M | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100971942; called by muse, mutect2, varscan2
- PCDHA9 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs782768269, COSV65325205; called by muse, mutect2, varscan2
- PCDHB12 | c.1392C>A p.N464K | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV99507981; called by muse, mutect2, varscan2
- PCDHB13 | c.1846G>A p.G616S | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1357651910, COSV99507982; called by muse, mutect2, varscan2
- PCDHB7 | c.829A>C p.I277L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.107); catalogued as COSV99177552; called by muse, mutect2, varscan2
- PCDHGA8 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as rs1462569715, COSV54008534; called by muse, mutect2, varscan2
- PCDHGB1 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs751339845, COSV53970008; called by muse, mutect2, varscan2
- PCLO | c.8049A>C p.R2683S | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100439126; called by muse, mutect2, varscan2
- PCNX2 | c.3340G>A p.A1114T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs775714681, COSV99269925; called by muse, mutect2, varscan2
- PCSK4 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99278910; called by muse, mutect2, varscan2
- PCSK5 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332369615, COSV65085156; called by muse, mutect2, varscan2
- PCSK6 | c.2318A>G p.H773R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs766960158, COSV100624585; called by mutect2, varscan2
- PCYOX1L | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.113); catalogued as rs775307182, COSV99199313; called by muse, mutect2, varscan2
- PDCD6IP | c.1081G>A p.V361M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs781385537, COSV100219231; called by muse, mutect2, varscan2
- PDE8B | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs746700414, COSV99367084, COSV99367776; called by muse, mutect2, varscan2
- PDE8B | c.1534G>A p.G512S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs774186250, COSV53741681; called by muse, mutect2, varscan2
- PDIK1L | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs1229628251, COSV100957733; called by muse, mutect2, varscan2
- PDZD2 | c.6529G>A p.A2177T | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99226758, COSV99227130; called by muse, varscan2
- PEDS1-UBE2V1 | c.869T>C p.L290P | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100441945; called by muse, mutect2, varscan2
- PELI2 | c.593del p.G198Afs*73 | Frame Shift Del (DEL) | VAF 30/91 reads (33%) | catalogued as COSV50713636; called by mutect2, pindel, varscan2
- PER1 | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs370403552; called by muse, mutect2, varscan2
- PFKFB4 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 37/107 reads (35%) | PolyPhen probably damaging (0.998); catalogued as rs142674001; called by muse, mutect2, varscan2
- PGR | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV99679289; called by mutect2, varscan2
- PGR | c.781G>C p.A261P | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99679291; called by mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 23/58 reads (40%) | catalogued as rs749326031; called by mutect2, varscan2
- PHF1 | c.440G>T p.R147M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100992701; called by muse, mutect2, varscan2
- PI4KA | c.4486C>T p.L1496= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99749162; called by muse, mutect2, varscan2
- PIGO | c.1361del p.G454Vfs*31 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | catalogued as COSV53054111, COSV53054694; called by mutect2, pindel, varscan2
- PIK3C2A | c.2609A>G p.D870G | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.538); catalogued as COSV99791376; called by muse, mutect2, varscan2
- PIP4K2A | c.753C>G p.N251K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.065); catalogued as rs185941375, COSV100114737; called by muse, mutect2, varscan2
- PITPNM3 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99339210; called by muse, mutect2, varscan2
- PITRM1 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs559025200, COSV99829791; called by muse, mutect2, varscan2
- PITX1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV99530761; called by muse, mutect2, varscan2
- PKD2 | c.2542C>T p.R848W | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99418015; called by muse, mutect2, varscan2
- PKHD1 | c.5944G>A p.E1982K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV61866315; called by muse, mutect2, varscan2
- PKHD1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV100584854; called by muse, mutect2, varscan2
- PKLR | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs555712170, COSV100713079; called by muse, mutect2, varscan2
- PLA2G1B | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100387583; called by muse, mutect2, varscan2
- PLAC9 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs760320471, COSV100953058; called by mutect2, varscan2
- PLB1 | c.1920G>A p.S640= | Splice Region (SNP) | VAF 26/57 reads (46%) | catalogued as rs778446335, COSV100215326; called by muse, mutect2, varscan2
- PLBD1 | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1210272639, COSV99554872; called by muse, mutect2, varscan2
- PLCD4 | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101346979; called by muse, mutect2, varscan2
- PLCE1 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); catalogued as COSV99597674; called by muse, mutect2
- PLCL1 | c.2498G>A p.G833D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as COSV101407332; called by muse, mutect2, varscan2
- PLEC | c.12368C>T p.T4123M (on ENST00000322810 / NM_201380.4; = p.T4013M on NM_000445.5) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs369056956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA4 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 12/44 reads (27%) | catalogued as rs1568550402, COSV99613445; called by muse, mutect2, varscan2
- PLEKHG1 | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs756100988, COSV100651470; called by muse, mutect2, varscan2
- PLEKHM3 | c.1811T>G p.L604R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as COSV101216970; called by muse, mutect2, varscan2
- PLK4 | c.168_169del p.R56Sfs*4 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs772584110; called by pindel, varscan2
- PLXNA4 | c.2762C>A p.A921D | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100327825; called by muse, mutect2, varscan2
- PLXNB2 | c.3592C>T p.L1198F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100834354; called by muse, mutect2, varscan2
- PLXNB3 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs782063016, COSV100738035; called by muse, mutect2, varscan2
- PLXND1 | c.3539C>T p.T1180M | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs528635984, COSV60714362; called by muse, mutect2, varscan2
- PMFBP1 | c.2713G>A p.A905T (on ENST00000537465; = p.A900T on NM_031293.3) | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs749839059, COSV99401661; called by muse, mutect2, varscan2
- PMS2 | c.1453A>G p.T485A | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99764355; called by muse, mutect2, varscan2
- POLE | c.5213C>A p.T1738N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100268631; called by muse, mutect2, varscan2
- POLE | c.5096C>A p.A1699D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV100268632; called by muse, mutect2, varscan2
- POLE | c.2091dup p.F699Vfs*11 | Frame Shift Ins (INS) | VAF 30/94 reads (32%) | catalogued as rs752846614; ClinVar: uncertain significance; called by mutect2, varscan2
- POLR1A | c.848T>C p.M283T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV99808592; called by muse, mutect2, varscan2
- POLR3B | c.1813G>A p.A605T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1451206257, COSV99943950; called by muse, mutect2, varscan2
- POU4F2 | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as COSV99850887; called by muse, mutect2, varscan2
- POU5F2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV101232962; called by muse, mutect2, varscan2
- PPP1R3A | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52884436, COSV99494657; called by muse, mutect2, varscan2
- PPP2R2C | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV100067449; called by muse, mutect2, varscan2
- PRAMEF2 | c.1368del p.C457Afs*39 | Frame Shift Del (DEL) | VAF 35/118 reads (30%) | catalogued as rs1557630098; called by mutect2, pindel, varscan2
- PRORP | c.148A>C p.T50P | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV99154993, COSV99156723; called by muse, mutect2, varscan2
- PRPF31 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs142874574; called by muse, mutect2, varscan2
- PSIP1 | c.419C>G p.T140S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV101051018; called by muse, mutect2, varscan2
- PSMD11 | c.938T>A p.L313H | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912695; called by muse, mutect2, varscan2
- PTCD1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99464667; called by muse, mutect2, varscan2
- PTCHD4 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs369189426; called by muse, mutect2, varscan2
- PTGFRN | c.950T>A p.F317Y | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs1371760712, COSV101277467; called by muse, mutect2, varscan2
- PTP4A1 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs773307144, COSV65715271; called by muse, mutect2, varscan2
- PTPN5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.091); catalogued as rs769885405, COSV100660007; called by muse, mutect2, varscan2
- PTPRF | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV63443726; called by muse, mutect2, varscan2
- PTPRT | c.1709C>A p.T570K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100631174, COSV104421192; called by muse, mutect2, varscan2
- PTPRT | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 23/55 reads (42%) | catalogued as COSV61958074; called by muse, mutect2, varscan2
- PXDN | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770394672, COSV53227060; called by muse, mutect2, varscan2
- PZP | c.1294T>C p.W432R | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs748801809, COSV99739938; called by muse, mutect2, varscan2
- R3HCC1L | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100107464, COSV100107603; called by muse, mutect2, varscan2
- RAB34 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748013391, COSV99973173; called by muse, mutect2, varscan2
- RAB40A | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100420880; called by muse, mutect2, varscan2
- RAI14 | c.2900A>C p.K967T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV99464833; called by muse, mutect2, varscan2
- RALGAPA1 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99356445; called by muse, mutect2, varscan2
- RAPGEF1 | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.014); catalogued as rs1208058639, COSV100940885; called by muse, mutect2, varscan2
- RARG | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs776186919, COSV100553768; called by muse, mutect2, varscan2
- RASA1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs753769946, COSV57205499; called by muse, varscan2
- RASA1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.75); catalogued as COSV99171304; called by muse, mutect2, varscan2
- RASA4 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); catalogued as rs781407757, COSV99500277; called by muse, mutect2, varscan2
- RASAL2 | c.2012G>A p.S671N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1243768034, COSV100862979; called by muse, mutect2, varscan2
- RASL10B | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs782263531; called by muse, mutect2, varscan2
- RB1CC1 | c.1920+2C>G p.X640_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV99213206; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV101208290; called by muse, mutect2, varscan2
- RBBP8 | c.1071del p.K357Nfs*3 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs754547584, COSV59093143; ClinVar: uncertain significance; called by mutect2, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as rs781825075; called by pindel, varscan2
- RBM22 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99556193; called by muse, mutect2, varscan2
- RBM22 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99556196; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM28 | c.1807C>A p.P603T | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV99775975; called by muse, mutect2, varscan2
- RBP4 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV101012309; called by muse, mutect2, varscan2
- RCC1 | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100868209; called by muse, mutect2, varscan2
- REPS2 | c.1879G>C p.A627P | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100381764; called by muse, mutect2, varscan2
- RERE | c.4530del p.M1511Cfs*48 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as COSV61941733; called by mutect2, varscan2
- RFPL2 | c.313T>A p.S105T | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.09); catalogued as rs1038505492, COSV99964692; called by muse, mutect2, varscan2
- RFWD3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.177); catalogued as rs763676630, COSV63097331; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS19 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.865); catalogued as rs747159624, COSV58658368; called by muse, mutect2, varscan2
- RGS22 | c.3181G>T p.D1061Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100693939; called by muse, mutect2
- RHBDF2 | c.1667G>A p.C556Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51684248; called by muse, mutect2, varscan2
- RIMS1 | c.3694C>A p.L1232I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.931); catalogued as COSV53466883; called by muse, mutect2, varscan2
- RIMS2 | c.1364G>A p.R455Q (on ENST00000666250 / NM_001348490.2; = p.R263Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); catalogued as COSV51653092; called by muse, mutect2, varscan2
- RINT1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.569); catalogued as COSV99994660; called by muse, mutect2, varscan2
- RIPOR3 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.261); catalogued as rs780922865, COSV50390432; called by muse, mutect2, varscan2
- RMC1 | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs371338099; called by muse, mutect2, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 10/15 reads (67%) | catalogued as rs757038390; called by mutect2, varscan2
- RNF175 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV99923836; called by muse, mutect2, varscan2
- RNF214 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as COSV100327108, COSV56119705; called by muse, mutect2, varscan2
- RNF32 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as COSV100311694; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNF43 | c.931del p.L311Sfs*108 | Frame Shift Del (DEL) | VAF 24/82 reads (29%) | catalogued as COSV68457393; called by mutect2, pindel, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RNF8 | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV100009952; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs752898741; called by mutect2, varscan2
- RP1 | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as COSV55124756; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL5 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV59874252; called by muse, mutect2, varscan2
- RPS5 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV52191477; called by muse, mutect2, varscan2
- RPTOR | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157546; called by muse, mutect2, varscan2
- RSBN1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.747); catalogued as rs760608559, COSV54733688; called by muse, mutect2, varscan2
- RSPH10B2 | c.33del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs868292826; called by mutect2, varscan2
- RTL5 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV65454052; called by muse, mutect2, varscan2
- RTN4IP1 | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs756187910, COSV100954249; called by muse, mutect2, varscan2
- RUBCN | c.1336A>G p.S446G | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV99585286; called by muse, mutect2, varscan2
- RYR2 | c.10823T>C p.L3608S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100773232; called by muse, mutect2
- SACS | c.11353A>T p.R3785W | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.215); catalogued as COSV101207826; called by muse, mutect2, varscan2
- SACS | c.5602G>T p.G1868* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV101207828; called by muse, mutect2, varscan2
- SALL3 | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs752632478, COSV101610077, COSV73306079; called by muse, mutect2, varscan2
- SART3 | c.2926A>T p.K976* (on ENST00000228284; = p.K958* on NM_014706.4) | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as COSV99934519; called by muse, mutect2, varscan2
- SCAPER | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV100239855; called by muse, mutect2, varscan2
- SCN10A | c.4990G>C p.D1664H | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101479566, COSV71862843; called by muse, mutect2, varscan2
- SCN4A | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs538978403, COSV71127470; called by muse, mutect2, varscan2
- SCN5A | c.1924A>C p.M642L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100351104; called by muse, mutect2
- SCN9A | c.209T>C p.M70T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1329565373, COSV100314536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCUBE2 | c.2465C>T p.T822I (on ENST00000649792 / NM_001367977.2; = p.T765I on NM_020974.3) | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497035; called by muse, mutect2, varscan2
- SDK1 | c.5765G>T p.W1922L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101269983; called by muse, mutect2, varscan2
- SEC11A | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99190294; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3C | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs143834638; called by muse, mutect2, varscan2
- SESN2 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV99456290; called by muse, mutect2, varscan2
812 further variants in this file (414 protein-altering or splice-affecting, 359 silent, 39 other) are not listed here.
